Gene-level copy-number profile of tumor specimen TCGA-R6-A6L6-01B from TCGA case TCGA-R6-A6L6, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G3; Age at diagnosis: 68.7 years (25,092 days).
Specimen TCGA-R6-A6L6-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-ESCA.9e7e52cc-47e6-4306-932d-662cf914a621.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-R6-A6L6-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a9da151a-6add-4c47-b38e-fc1dcb327606

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 21; copy number 1: 228; copy number 2: 125; copy number 3: 11,168; copy number 4: 28,190; copy number 5: 1,368; copy number 6: 10,497; copy number 7: 5,336; copy number 8: 188; copy number 9: 1,744; copy number 10: 74; copy number 11: 372; copy number 12: 86; copy number 13: 77; copy number 14: 6; copy number 15: 16; copy number 17: 50; copy number 18: 91; copy number 24: 27; copy number 27: 30; copy number 39: 20; copy number 54: 105.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-R6-A6L6-01B-11D-A33D-01): tumor purity 0.26, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 21 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:5,962,842–6,736,750, 4 genes (within-gene range 0–1): AC087857.1, AC026167.1, AC027119.1, AC069277.1.
- chr3:60,616,822–60,618,079, 2 genes: AC104164.2, MIR548BB.
- chr5:131,423,921–132,080,133, 15 genes: RAPGEF6, AC008695.1, AC008497.1, FNIP1, ACTBP4, AC005593.1, MEIKIN, AC034228.3, AC034228.2, ACSL6, ACSL6-AS1, AC034228.1, IL3, CSF2, AC034216.1.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,698 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:89,047,442–89,590,097, 5 genes, copy number 10: GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6.
- chr4:138,309,613–140,779,141, 56 genes, copy number 10 (within-gene range 3–10): LINC00499, LINC00500, AC105416.1, AC098859.1, AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3, AC112236.1, MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253, AC131182.1, SCOC, SCOC-AS1, NDUFB4P9, RPL14P3, CLGN, MGAT4D, AC093671.1, ELMOD2, UCP1, AC108019.2, RN7SL152P, AC108019.1, TBC1D9, TNRC18P1, RNY1P14, AC096733.1, AC096733.2, Y_RNA.
- chr8:78,805,293–97,625,079, 292 genes, copy number 9 (broad region; genes not listed).
- chr8:98,371,228–131,712,980, 458 genes, copy number 9–18 (broad region; genes not listed).
- chr8:135,234,131–142,545,009, 69 genes, copy number 12 (within-gene range 5–12) (broad region; genes not listed).
- chr13:93,226,807–102,402,457, 141 genes, copy number 9–14 (within-gene range 7–14) (broad region; genes not listed).
- chr17:38,530,031–41,966,503, 210 genes, copy number 17–54 (within-gene range 4–54) (broad region; genes not listed).
- chr18:9,646,110–9,960,021, 13 genes, copy number 10: LINC02856, KRT18P8, RAB31, AP000902.1, ZNF415P1, RN7SL862P, AC006238.2, RNA5SP449, PIGPP4, TXNDC2, AC006238.1, VAPA, RNA5SP450.
- chr20:87,250–16,053,197, 291 genes, copy number 9 (within-gene range 6–9) (broad region; genes not listed).
- chr20:15,280,764–64,313,132, 1,163 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 228. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
